Gene-level copy-number profile of specimen HCM-CSHL-0247-C18-85A from HCMI case HCM-CSHL-0247-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 76.5 years (27,936 days).
Specimen HCM-CSHL-0247-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 835e26b1-e2a0-4e9a-a796-28f435080148.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0247-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/e4168717-ea26-4a3c-86c5-2bec3116c206

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 14,674; copy number 2: 36,755; copy number 3: 5,544; copy number 4: 1,380; copy number 5: 6; copy number 7: 11.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:83,940,554–84,490,765, 3 genes (within-gene range 0–1): EDIL3, RNU6-448P, EDIL3-DT.
- chr8:12,448,013–12,665,588, 3 genes (within-gene range 0–1): ENPP7P6, AC068587.4, AC130352.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:89,047,442–90,030,495, 6 genes, copy number 5: GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3.
- chr13:46,455,131–46,897,076, 11 genes, copy number 7: LINC01198, AL138686.2, OR7E101P, AL138686.1, COX17P1, FKBP1AP3, LRCH1, AL359880.1, ESD, HTR2A, HTR2A-AS1.

Autosomal genes at a single copy (total copy number 1): 12,332. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
